Gene-level copy-number profile of tumor specimen TCGA-AR-A254-01A from TCGA case TCGA-AR-A254, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 50.0 years (18,270 days).
Specimen TCGA-AR-A254-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.7385c5f6-5fb1-4d45-a17d-93636a161c7c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A254-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/825859cd-eaef-483a-a9f0-c64f4c969234

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 922; copy number 2: 10,818; copy number 3: 35,608; copy number 4: 4,480; copy number 5: 2,284; copy number 6: 2,056; copy number 7: 1,026; copy number 8: 250; copy number 9: 84; copy number 10: 90; copy number 11: 1,578; copy number 12: 200; copy number 13: 43; copy number 14: 34; copy number 15: 47; copy number 16: 57; copy number 17: 35; copy number 18: 42; copy number 19: 41; copy number 20: 37; copy number 27: 21; copy number 39: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A254-01A-21D-A166-01): tumor purity 0.45, ploidy 3.38, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,640 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:98,660,388–98,760,500, 2 genes, copy number 8: AC095031.1, SNX7.
- chr1:105,587,575–106,865,316, 12 genes, copy number 10: LINC01676, SEPTIN2P1, AL512844.2, AL512844.1, LINC01677, AL355306.2, AL355306.1, AL499605.1, AL596327.1, MTATP6P14, MTCO1P14, LINC01661.
- chr1:119,031,216–120,355,148, 41 genes, copy number 13: WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1.
- chr1:143,343,180–163,923,873, 887 genes, copy number 7–9 (broad region; genes not listed).
- chr1:203,626,787–206,970,625, 113 genes, copy number 7 (broad region; genes not listed).
- chr5:56,975,593–57,899,162, 13 genes, copy number 7–18: AC114973.1, AC034244.1, AC034244.2, Y_RNA, GPBP1, AC025470.1, AC025470.2, SALL4P1, ACTBL2, LINCR-0003, AC008780.1, AC106822.1, LINC02225.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 11 (broad region; genes not listed).
- chr10:2,150,480–2,618,739, 7 genes, copy number 9: AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2, AL713851.1.
- chr10:6,824,275–8,973,468, 29 genes, copy number 7–8 (within-gene range 5–8): AL392086.3, LINC02665, AL590095.1, SFMBT2, COX6CP17, AL139125.1, LINC02642, RNU6-535P, AL445070.1, ITIH5, ITIH2, KIN, ATP5F1C, TAF3, AL353754.1, GATA3, GATA3-AS1, AL390294.1, PRPF38AP1, LINC00708, AL390835.1, AC025946.1, AC025946.2, KRT8P37, CHCHD3P1, RNA5SP299, AL355333.1, LINC02676, AC044784.1.
- chr10:9,721,963–9,878,060, 2 genes, copy number 13 (within-gene range 5–13): HSP90AB7P, LINC02663.
- chr10:10,784,437–11,398,792, 10 genes, copy number 9: SFTA1P, CELF2, LINC00710, AL136369.2, AL136369.1, AL162408.1, CELF2-AS2, AL136320.1, CELF2-AS1, AC026887.1.
- chr10:12,244,751–13,668,445, 34 genes, copy number 14–20: AL512770.1, RN7SL198P, CAMK1D, AL391314.1, RNU6ATAC39P, AL731559.1, MIR4480, MIR4481, MIR548Q, AL353586.1, CCDC3, RNA5SP300, RPL5P25, OPTN, SNRPGP5, AL355355.2, AL355355.1, BTBD7P1, RPL36AP36, MCM10, RNU6-6P, UCMA, PHYH, RBISP1, SEPHS1, AL355870.2, AL355870.1, BEND7, Y_RNA, AL590677.1, PRPF18, RPL6P24, AL157392.5, AL157392.3.
- chr10:13,675,646–13,871,175, 5 genes, copy number 20: AL157392.4, AL157392.1, RNA5SP301, AL157392.2, NUTF2P5.
- chr10:53,291,072–53,458,288, 2 genes, copy number 8–18: AC036101.1, RNA5SP318.
- chr10:55,247,755–61,026,420, 47 genes, copy number 8–18: AC016822.1, AL355314.1, AL355314.2, MTRNR2L5, GAPDHP21, AC069545.1, ZWINT, AC010996.1, AC025039.1, MIR3924, AL731534.1, AC006484.1, MRPS35P3, AC026884.1, IPMK, TPT1P10, CISD1, AC016396.1, AC016396.2, UBE2D1, TFAM, BICC1, FAM133CP, RN7SKP196, LINC00844, RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1, AL355474.1, MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2, ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845.
- chr10:62,520,448–62,672,011, 1 gene, copy number 15 (within-gene range 5–15): AC067752.1.
- chr10:71,319,259–77,793,176, 159 genes, copy number 8–15 (within-gene range 4–15) (broad region; genes not listed).
- chr10:78,943,328–79,827,602, 25 genes, copy number 7–12: ZMIZ1-AS1, AL356753.1, ZMIZ1, PPIF, ZCCHC24, AL133481.1, TPRX1P1, AL133481.3, AL133481.2, EIF5AL1, BX248123.1, RPS12P18, SFTPA2, MBL3P, SFTPA3P, SFTPA1, LINC02679, AL132656.2, NUTM2B-AS1, AL132656.3, AL132656.4, BEND3P3, AL132656.1, NUTM2B, AL135925.1.
- chr10:127,734,562–128,320,214, 11 genes, copy number 7: AL391005.1, FOXI2, BUB1P1, CLRN3, PTPRE, AL158166.2, AL158166.1, AL390236.1, MKI67, LINC01163, AL390763.1.
- chr10:132,036,336–133,761,125, 71 genes, copy number 11–12 (broad region; genes not listed).
- chr17:39,401,793–40,885,242, 76 genes, copy number 27–39 (broad region; genes not listed).
- chr17:41,754,604–42,021,376, 12 genes, copy number 9 (within-gene range 2–9): JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1, KLHL11, ACLY, AC125257.2, TTC25, CNP, DNAJC7.
- chr17:47,896,150–53,106,358, 193 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr20:38,098,414–38,729,372, 32 genes, copy number 10: RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1.
- chr20:50,586,108–50,691,542, 1 gene, copy number 19 (within-gene range 3–19): RIPOR3.
- chr20:50,645,471–55,684,915, 63 genes, copy number 15–19 (within-gene range 6–32) (broad region; genes not listed).
- chr20:55,997,357–64,313,132, 258 genes, copy number 8–20 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
